Surgical pathology report (de-identified scan), TCGA case TCGA-61-1895, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1895-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, SALPINGO-OOPHORECTOMY –

- A. HIGH-GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVING LEFT OVARY, 9.0 CM IN GREATEST DIMENSION.
- B. ADENOCARCINOMA INVOLVES SURFACE OF OVARY.
- C. FOCAL LYMPHOVASCULAR INVASION.
- D. HIGH-GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVES WALL AND SEROSAL SURFACE OF FALLOPIAN TUBE.
- E. FALLOPIAN TUBE WITH ACUTE AND CHRONIC SALPINGITIS.

PART 2: RIGHT ADNEXA, SALPINGO-OOPHORECTOMY –

- A. HIGH-GRADE PAPILLARY SEROUS ADENOCARCINOMA INVOLVING RIGHT OVARY, 1.7 CM IN GREATEST DIMENSION.
- B. ADENOCARCINOMA INVOLVES SURFACE OF OVARY.
- C. UNINVOLVED OVARY WITH PHYSIOLOGIC CHANGES, HEMORRHAGIC CORPUS LUTEAL CYST, EPITHELIAL INCLUSION CYST AND CALCIFICATIONS IN CYST WALL.
- D. FALLOPIAN TUBE WITH PARATUBAL CYST.
- E. PATHOLOGIC STAGE pT3b pNO pMX.

PART 3: UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY (146 GRAMS) –

- A. ENDOMETRIAL POLYP.
- B. PROLIFERATIVE ENDOMETRIUM.
- C. ADENOMYOSIS.
- D. ENDOCERVICAL/LOWER UTERINE SEGMENT POLYP.
- E. CHRONIC CYSTIC CERVICITIS.

PART 4: LYMPH NODES, RIGHT PELVIC, DISSECTION –

ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: LYMPH NODES, RIGHT COMMON AND PERIAORTIC, DISSECTION –

THREE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/3).

PART 6: PERICOLIC GUTTER, BIOPSY –

FIBROADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

PART 7: ANTERIOR CUL-DE-SAC, BIOPSY –

FIBROADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

PART 8: POSTERIOR CUL-DE-SAC, BIOPSY –

SQUAMOUS EPITHELIAL-LINED TISSUE, NEGATIVE FOR CARCINOMA.

PART 9: LYMPH NODES, LEFT PELVIC, DISSECTION –

FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

PART 10: LYMPH NODES, LEFT PELVIC, DISSECTION –

TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 11: LEFT PERICOLIC GUTTER, BIOPSY –

FIBROADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

PART 12: SIGMOID COLON, PARTIAL RESECTION –

- A. SIGMOID COLON WITH FOCUS OF HIGH-GRADE PAPILLARY SEROUS ADENOCARCINOMA IN PERICOLIC FAT.
- B. MARGINS NEGATIVE FOR CARCINOMA.

PART 13: OMENTUM, OMENTECTOMY –

NEGATIVE FOR CARCINOMA.

PART 14: DIAPHRAGM, BIOPSY –

FIBROADIPOSE TISSUE AND SKELETAL MUSCLE, NEGATIVE FOR CARCINOMA.

[page 2 of 2]
SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 9 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	> or = 25 (3)
HISTOLOGIC GRADE (serous tumors):	High grade
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Intact
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Fallopian Tubes, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	< 2 cm.
ASSOCIATED OTHER LESION:	Surface epithelial inclusion
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	No
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 10
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0

T STAGE, PATHOLOGIC:

T STAGE, PATHOLOGIC continued on next page**

T STAGE, PATHOLOGIC continued**

N STAGE, PATHOLOGIC:

pT3b

M STAGE, PATHOLOGIC:

pN0

FIGO STAGE:

pMX

IIIB

Source: NCI Genomic Data Commons file a069e9ca-ad5c-4446-8c6c-5d0aa51c2521 (TCGA-61-1895.B33D3A26-D864-4669-B06E-1335BE4E9E3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).